Somatic mutation profile of tumor specimen TCGA-DD-AADW-01A (aliquot TCGA-DD-AADW-01A-11D-A38X-10) from TCGA case TCGA-DD-AADW, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 48.7 years (17,781 days).
Specimen TCGA-DD-AADW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7b95d299-168f-4998-be06-dab76d85fc06.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AADW-10A (Blood Derived Normal), aliquot TCGA-DD-AADW-10A-01D-A38X-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4cf4f17e-e57a-499e-9730-955d7866ae47

The open-access MAF lists 54 somatic variants for this specimen: 39 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 14, Splice Site 2, Intron 1, In Frame Del 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.528C>G p.C176W | Missense Mutation (SNP) | VAF 8/68 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519980, COSV52687391, COSV52701599, COSV52735850, COSV99377692; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ANK2 | c.8924G>T p.S2975I | Missense Mutation (SNP) | VAF 67/133 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.466); catalogued as COSV100002491; called by muse, mutect2, varscan2
- ANLN | c.2195C>T p.T732I | Missense Mutation (SNP) | VAF 28/253 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs766163761, COSV99732507; called by muse, mutect2, varscan2
- ARFGEF1 | c.1714G>C p.D572H | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.651); catalogued as COSV99142909; called by muse, mutect2, varscan2
- ATRNL1 | c.2911C>T p.H971Y | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1229952017, COSV100371527; called by muse, mutect2, varscan2
- C6orf15 | c.665G>A p.G222D | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as rs761443943, COSV99456986; called by muse, mutect2, varscan2
- CATSPER1 | c.1528T>C p.F510L | Missense Mutation (SNP) | VAF 19/204 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.159); catalogued as COSV100376060; called by muse, mutect2
- CD7 | c.7G>C p.G3R | Missense Mutation (SNP) | VAF 18/310 reads (6%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as COSV99486282; called by muse, mutect2
- CDK18 | c.661G>A p.V221M (on ENST00000506784 / NM_212503.3; = p.V191M on NM_002596.4) | Missense Mutation (SNP) | VAF 24/325 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs757990902, COSV100774060; called by muse, mutect2
- COL8A2 | c.1511G>A p.G504E | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100291265; called by muse, mutect2, varscan2
- HSPH1 | c.1124G>T p.G375V | Missense Mutation (SNP) | VAF 54/66 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100185018; called by muse, mutect2, varscan2
- HUWE1 | c.5872G>A p.A1958T | Missense Mutation (SNP) | VAF 67/81 reads (83%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.971); catalogued as COSV99473046; called by muse, mutect2, varscan2
- KRT83 | c.782A>T p.D261V | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV99531720; called by muse, mutect2, varscan2
- LIFR | c.520A>G p.I174V | Missense Mutation (SNP) | VAF 259/584 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV99664660; called by muse, mutect2, varscan2
- LRRC37A3 | c.3955C>A p.P1319T | Missense Mutation (SNP) | VAF 48/184 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.143); catalogued as COSV100141172; called by muse, mutect2, varscan2
- MBD5 | c.2812C>G p.L938V | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.029); catalogued as COSV101290144, COSV68697034; called by muse, mutect2, varscan2
- MLXIPL | c.2420C>G p.S807C | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100515423; called by muse, mutect2, varscan2
- MSRB3 | c.56T>C p.L19P | Missense Mutation (SNP) | VAF 12/157 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.38); catalogued as rs1346209898, COSV100378033; called by muse, mutect2
- MYCBP2 | c.1218G>T p.E406D (on ENST00000357337; = p.E444D on NM_015057.5) | Missense Mutation (SNP) | VAF 70/182 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV100630826; called by muse, mutect2, varscan2
- NEGR1 | c.981T>A p.D327E | Missense Mutation (SNP) | VAF 42/468 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100164476; called by muse, mutect2
- PACC1 | c.361G>A p.G121S | Missense Mutation (SNP) | VAF 17/199 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs369443875; called by muse, mutect2
- PADI3 | c.247C>G p.P83A | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT tolerated (1); PolyPhen possibly damaging (0.457); catalogued as COSV100968514; called by muse, mutect2, varscan2
- RFK | c.43G>A p.G15S | Missense Mutation (SNP) | VAF 52/132 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100946901; called by muse, mutect2, varscan2
- RRBP1 | c.517G>T p.A173S | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.054); catalogued as COSV99854237; called by muse, mutect2, varscan2
- RTL9 | c.3455T>C p.L1152S | Missense Mutation (SNP) | VAF 21/258 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV101511732; called by muse, mutect2
- SGTB | c.803+1G>A p.X268_splice | Splice Site (SNP) | VAF 75/140 reads (54%) | catalogued as rs1362882252, COSV66817353; called by muse, mutect2, varscan2
- SLC35C1 | c.561G>C p.Q187H | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100029424; called by muse, mutect2
- SLC8A2 | c.1496G>A p.G499D | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as COSV99370116; called by muse, mutect2, varscan2
- SMPD2 | c.740G>T p.G247V | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.867); catalogued as COSV99238029; called by muse, mutect2, varscan2
- TCP11 | c.667A>G p.I223V (on ENST00000512012; = p.I161V on NM_018679.5) | Missense Mutation (SNP) | VAF 95/233 reads (41%) | SIFT tolerated (0.82); PolyPhen benign (0.026); catalogued as COSV99774377; called by muse, mutect2, varscan2
- TTC39C | c.193G>A p.G65R (on ENST00000317571 / NM_001135993.2; = p.G4R on NM_153211.4) | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100455466; called by muse, varscan2
- UBE2K | c.584A>G p.E195G | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV99787277; called by muse, mutect2, varscan2
- WDR7 | c.2776A>G p.T926A | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.038); catalogued as COSV99589734; called by muse, mutect2, varscan2
- XIRP2 | c.2080G>C p.G694R (on ENST00000628543; = p.G869R on NM_152381.6) | Missense Mutation (SNP) | VAF 14/402 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV54732810, COSV99744620; called by muse, mutect2
- ZFHX4 | c.1071T>G p.D357E | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.99); catalogued as COSV99264547; called by muse, mutect2, varscan2
- SERPINE2 | c.985_985+3del p.X329_splice | Splice Site (DEL) | VAF 13/88 reads (15%) | called by mutect2, pindel, varscan2
- TULP4 | c.2190_2201del p.V731_A734del | In Frame Del (DEL) | VAF 37/105 reads (35%) | called by mutect2, pindel, varscan2
- ZFHX4 | c.4598_4599dup p.F1534Nfs*37 | Frame Shift Ins (INS) | VAF 14/160 reads (9%) | called by mutect2, pindel
- ZFHX4 | c.4871_4878del p.A1624Gfs*46 | Frame Shift Del (DEL) | VAF 14/146 reads (10%) | called by mutect2, pindel
- ATAD5 | c.9G>A p.G3= | Silent (SNP) | VAF 25/76 reads (33%) | catalogued as COSV100430049; called by muse, mutect2
- ATRNL1 | c.261G>T p.G87= | Silent (SNP) | VAF 4/77 reads (5%) | catalogued as rs782184348; called by muse, mutect2
- FGA | c.1776A>G p.G592= | Silent (SNP) | VAF 27/41 reads (66%) | catalogued as COSV100120506; called by muse, mutect2, varscan2
- H3C1 | c.288G>C p.A96= | Silent (SNP) | VAF 40/124 reads (32%) | catalogued as COSV99772107; called by muse, mutect2
- HMX3 | c.324C>T p.H108= | Silent (SNP) | VAF 55/132 reads (42%) | catalogued as COSV100774147; called by muse, mutect2, varscan2
- IFNA8 | c.54A>T p.S18= | Silent (SNP) | VAF 27/70 reads (39%) | catalogued as COSV101206914; called by muse, mutect2, varscan2
- KPRP | c.939C>T p.P313= | Silent (SNP) | VAF 23/119 reads (19%) | catalogued as COSV100908735; called by muse, mutect2, varscan2
- MCM7 | c.1383C>A p.V461= | Silent (SNP) | VAF 8/84 reads (10%) | catalogued as COSV100385018; called by muse, mutect2
- N6AMT1 | c.123C>A p.A41= | Silent (SNP) | VAF 15/223 reads (7%) | catalogued as rs767074452, COSV58134860; called by muse, mutect2
- OR5L1 | c.807T>C p.D269= | Silent (SNP) | VAF 11/101 reads (11%) | catalogued as COSV100450103; called by muse, mutect2, varscan2
- SPATA31A1 | c.348G>A p.Q116= | Silent (SNP) | VAF 41/384 reads (11%) | called by muse, mutect2, varscan2
- TRGC2 | c.168A>G p.G56= | Silent (SNP) | VAF 31/104 reads (30%) | called by muse, mutect2, varscan2
- YIF1B | c.651C>A p.L217= (on ENST00000339413 / NM_001039673.3; = p.L202= on NM_001039671.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/141 reads (5%) | catalogued as COSV100007983; called by muse, mutect2
- ZNF781 | c.726G>T p.L242= | Silent (SNP) | VAF 40/70 reads (57%) | catalogued as COSV100669292; called by muse, mutect2, varscan2
- ATP8B2 | c.1133+90G>T | Intron (SNP) | VAF 74/354 reads (21%) | catalogued as COSV100528092; called by muse, mutect2, varscan2
